Somatic mutation profile of tumor specimen 0DHY4W from CCDI case PBBUZK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 5.1 years (1,871 days).
Specimen 0DHY4W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1730f4b-1353-4813-a58f-5e4656da539a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHY2X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a53d0450-a01f-4eea-960d-66a0f31078a2

The open-access MAF lists 47 somatic variants for this specimen: 28 protein-altering or splice-affecting, 6 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 6, 3'UTR 6, Intron 5, 5'UTR 2, Nonsense Mutation 2, Splice Region 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACO1 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 190/402 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs137954533; called by muse, mutect2, varscan2
- BCOR | c.3810G>A p.W1270* (on ENST00000378444 / NM_001123385.2; = p.W1236* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 245/512 reads (48%) | catalogued as COSV60717728; called by muse, mutect2, varscan2
- CHD6 | c.3825C>G p.D1275E | Missense Mutation (SNP) | VAF 269/934 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs1167623945; called by muse, mutect2, varscan2
- FLT1 | c.3154G>A p.D1052N | Missense Mutation (SNP) | VAF 111/260 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374177896; called by muse, mutect2, varscan2
- GLT8D1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 44/743 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs201758107, COSV56477213; called by muse, mutect2
- LORICRIN | c.683G>C p.G228A | Missense Mutation (SNP) | VAF 551/823 reads (67%) | PolyPhen probably damaging (0.949); catalogued as rs867823487; called by muse, mutect2, varscan2
- LYPLA2 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 222/443 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs375628913; called by muse, mutect2, varscan2
- MYH6 | c.4744G>T p.D1582Y | Missense Mutation (SNP) | VAF 367/1128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62455027; called by muse, mutect2, varscan2
- TBX10 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 195/675 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs772929837, COSV56875118; called by muse, mutect2, varscan2
- USP32 | c.3088G>A p.G1030R | Missense Mutation (SNP) | VAF 249/1167 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs1404874439; called by muse, mutect2, varscan2
- CD1A | c.471G>T p.M157I | Missense Mutation (SNP) | VAF 207/618 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH22 | c.1456A>G p.R486G | Missense Mutation (SNP) | VAF 349/1140 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- COPA | c.2299T>A p.L767I | Missense Mutation (SNP) | VAF 143/445 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- DDX4 | c.1796T>C p.V599A | Missense Mutation (SNP) | VAF 44/698 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ERP27 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 118/727 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FGF2 | c.681+2dup p.X227_splice | Splice Site (INS) | VAF 135/309 reads (44%) | called by mutect2, varscan2
- HSF5 | c.620C>A p.S207* | Nonsense Mutation (SNP) | VAF 265/1057 reads (25%) | called by muse, mutect2, varscan2
- LAMB2 | c.3110-4A>G | Splice Region (SNP) | VAF 305/619 reads (49%) | called by muse, mutect2, varscan2
- LONRF1 | c.2294_2307del p.T765Rfs*4 | Frame Shift Del (DEL) | VAF 124/842 reads (15%) | called by mutect2, varscan2
- MYO1C | c.1765A>C p.S589R (on ENST00000648651 / NM_001080779.2; = p.S554R on NM_033375.5) | Missense Mutation (SNP) | VAF 209/461 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- NCLN | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 667/1127 reads (59%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- NOL9 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 61/385 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NTNG2 | c.1532G>C p.R511P | Missense Mutation (SNP) | VAF 19/496 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.039); called by muse, mutect2
- PJA1 | c.1082G>T p.C361F (on ENST00000361478 / NM_145119.4; = p.C173F on NM_022368.5) | Missense Mutation (SNP) | VAF 280/660 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0); called by mutect2, varscan2
- PTGS2 | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 268/554 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNF113A | c.764A>T p.D255V | Missense Mutation (SNP) | VAF 205/441 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- SLC9A4 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 224/658 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- XAGE5 | c.272C>G p.P91R | Missense Mutation (SNP) | VAF 254/625 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- CDH1 | c.1791T>C p.P597= | Silent (SNP) | VAF 203/480 reads (42%) | called by muse, mutect2, varscan2
- DPP3 | c.1116C>T p.D372= | Silent (SNP) | VAF 253/920 reads (28%) | called by muse, mutect2, varscan2
- MGAT5B | c.204C>T p.R68= | Silent (SNP) | VAF 248/1618 reads (15%) | catalogued as rs376780333, COSV56927211; called by muse, mutect2
- MNDA | c.336G>C p.A112= | Silent (SNP) | VAF 259/880 reads (29%) | catalogued as COSV63740866; called by muse, mutect2, varscan2
- RAMP2 | c.12C>G p.L4= | Silent (SNP) | VAF 327/635 reads (51%) | called by muse, mutect2, varscan2
- TCHH | c.1179G>A p.Q393= | Silent (SNP) | VAF 38/334 reads (11%) | called by muse, varscan2
- ASF1B | c.402+84G>C | Intron (SNP) | VAF 137/383 reads (36%) | called by muse, mutect2, varscan2
- ATAD1 | c.*66T>C | 3'UTR (SNP) | VAF 112/217 reads (52%) | called by muse, mutect2, varscan2
- DNAAF3 | c.1164-34C>G | Intron (SNP) | VAF 42/338 reads (12%) | catalogued as rs1328317500; called by muse, mutect2, varscan2
- GKN2 | c.472+37T>C | Intron (SNP) | VAF 104/575 reads (18%) | called by muse, mutect2, varscan2
- LAYN | c.*79C>T | 3'UTR (SNP) | VAF 46/113 reads (41%) | called by muse, mutect2, varscan2
- MIPEP | c.-73C>G | 5'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- MS4A6E | c.-48C>G | 5'UTR (SNP) | VAF 118/338 reads (35%) | called by muse, mutect2, varscan2
- MSRB3 | c.*25A>G | 3'UTR (SNP) | VAF 109/582 reads (19%) | called by muse, mutect2, varscan2
- NPL | c.230+35G>A | Intron (SNP) | VAF 146/1197 reads (12%) | catalogued as rs747370208; called by muse, mutect2, varscan2
- PTDSS1 | c.*20G>T | 3'UTR (SNP) | VAF 243/1337 reads (18%) | called by muse, mutect2, varscan2
- SDR39U1 | c.206+47C>T | Intron (SNP) | VAF 198/669 reads (30%) | called by muse, mutect2, varscan2
- SORCS3 | c.*89T>C | 3'UTR (SNP) | VAF 64/71 reads (90%) | called by muse, mutect2, varscan2
- ZNF141 | c.*9139A>G | 3'UTR (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
